Gene-level copy-number profile of tumor specimen HCM-SANG-1310-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-1310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1310-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ea8deab-3ca8-485e-8cef-e5ff5518c382.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1310-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,752 have no estimate.
https://portal.gdc.cancer.gov/files/8c285651-b86f-47ac-8c5e-bac0b8040097

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 2,943; copy number 2: 24,749; copy number 3: 19,272; copy number 4: 9,567; copy number 5: 2,207; copy number 6: 31; copy number 7: 22.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene (within-gene range 0–2): AC008833.1.
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr7:6,866,658–6,880,626, 2 genes: OR7E136P, OR7E59P.
- chr9:6,639,139–6,727,438, 8 genes (within-gene range 0–1): RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,735,076, 1 gene (within-gene range 0–1): PRELID3BP11.
- chr9:41,131,306–41,480,548, 8 genes (within-gene range 0–2): CBWD6, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1.
- chr9:64,810,865–64,889,063, 4 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr10:86,756,601–88,259,372, 48 genes: BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr17:18,432,051–18,506,313, 7 genes: KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,260 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–11,102,100, 13 genes, copy number 5: CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1.
- chr1:34,166,883–34,277,292, 2 genes, copy number 6: C1orf94, AC115286.1.
- chr1:105,433,994–112,371,107, 168 genes, copy number 5 (broad region; genes not listed).
- chr2:43,091,388–43,132,482, 2 genes, copy number 5: RNU6-242P, LINC02580.
- chr2:101,696,850–103,276,138, 23 genes, copy number 5: MAP4K4, LINC01127, IL1R2, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1.
- chr2:106,063,246–108,509,415, 49 genes, copy number 5 (within-gene range 3–5): ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2.
- chr4:69,280,475–69,358,177, 3 genes, copy number 5: UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 5 (within-gene range 2–5): UGT2B24P.
- chr5:58,198–16,617,058, 278 genes, copy number 5 (broad region; genes not listed).
- chr5:16,617,225–16,623,095, 2 genes, copy number 5: AC022113.1, Y_RNA.
- chr5:17,065,598–17,276,843, 2 genes, copy number 5 (within-gene range 4–5): BASP1, BASP1-AS1.
- chr5:17,156,971–45,895,970, 390 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:43,450,352–44,450,425, 43 genes, copy number 5 (within-gene range 4–5): DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642.
- chr6:55,327,469–55,940,624, 5 genes, copy number 6–7: GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36.
- chr6:108,986,437–109,383,666, 11 genes, copy number 6: SESN1, AL390208.1, RNU6-653P, CEP57L1, CCDC162P, AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2.
- chr6:142,748,443–170,738,536, 462 genes, copy number 5 (broad region; genes not listed).
- chr9:41,657,708–41,699,072, 2 genes, copy number 6: FAM242F, Y_RNA.
- chr9:41,890,314–43,045,120, 32 genes, copy number 5: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr10:50,021,182–50,067,803, 1 gene, copy number 5 (within-gene range 2–5): FAM21EP.
- chr10:50,067,888–50,965,220, 22 genes, copy number 5: WASHC2A, SLC9A3P1, ASAH2, DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2.
- chr10:58,512,872–59,364,075, 10 genes, copy number 5: BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1.
- chr10:61,662,929–62,919,900, 15 genes, copy number 5: CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2.
- chr10:103,479,603–103,592,552, 4 genes, copy number 5: NEURL1-AS1, NEURL1, AL121929.1, AL121929.3.
- chr10:112,446,998–112,818,744, 1 gene, copy number 5 (within-gene range 4–5): VTI1A.
- chr10:112,634,170–113,167,678, 9 genes, copy number 5: MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30.
- chr10:117,128,521–118,342,328, 20 genes, copy number 7: VAX1, MIR3663HG, MIR3663, RPL12P26, KCNK18, AL731557.1, SLC18A2, AL391988.1, PDZD8, AC005871.2, EMX2OS, EMX2, AC005871.1, LINC02674, AL513324.1, RAB11FIP2, AC022395.1, CASC2, AL354863.1, FAM204A.
- chr10:118,784,563–119,997,709, 31 genes, copy number 5: AL157388.1, RPL17P36, LDHAP5, NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1, RAD1P1, RPS8P4, BAG3, TXNP1, INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2.
- chr10:127,907,103–128,960,062, 9 genes, copy number 6: PTPRE, AL158166.2, AL158166.1, AL390236.1, MKI67, LINC01163, AL390763.1, LINC02667, AL355537.1.
- chr12:118,981,541–119,163,051, 2 genes, copy number 5 (within-gene range 3–5): SRRM4, AC087885.1.
- chr12:119,031,039–119,877,320, 15 genes, copy number 5: AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934, CCDC60, AC002070.1, TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178.
- chr13:39,209,116–39,791,665, 4 genes, copy number 6 (within-gene range 4–6): LHFPL6, COG6, MIR4305, RNY4P14.
- chr20:37,178,410–51,562,831, 346 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:52,192,159–53,609,907, 20 genes, copy number 5 (within-gene range 4–5): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217.
- chr20:53,875,252–64,327,972, 263 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
